Somatic mutation profile of tumor specimen HTMCP-03-06-02327-01A (aliquot HTMCP-03-06-02327-01A-01D-9006) from CGCI case HTMCP-03-06-02327, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02327-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 456f3527-f3a0-4b9b-9b34-2d1222d775b6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02327-10A (Blood Derived Normal), aliquot HTMCP-03-06-02327-10A-01D-9006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd28bcf3-85e4-49d3-afbb-2addc178b23b

The open-access MAF lists 65 somatic variants for this specimen: 46 protein-altering or splice-affecting, 14 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 2, Splice Region 1, 5'Flank 1, Intron 1, RNA 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.40C>T p.R14* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | hotspot (GDC flag); catalogued as rs1362274408, COSV55920408; called by muse, mutect2, varscan2
- WDR45 | c.827+1G>A p.X276_splice (on ENST00000376372 / NM_001029896.2; = p.X277_splice on NM_007075.3) | Splice Site (SNP) | VAF 42/133 reads (32%) | catalogued as rs1557083958, CS1211569, COSV100540289, COSV59876430, COSV59876939; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.1832C>T p.S611F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.61); catalogued as COSV70032259; called by muse, mutect2, varscan2
- AFF3 | c.2758G>A p.D920N | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as rs202104245, COSV57863774; called by muse, mutect2, varscan2
- CFAP100 | c.1510G>A p.V504M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); catalogued as rs778286422; called by muse, mutect2, varscan2
- CROCC | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | catalogued as COSV100978020; called by muse, mutect2
- FER1L6 | c.3335C>T p.S1112L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV67551312; called by muse, mutect2, varscan2
- GRM1 | c.3431C>T p.A1144V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs1312527333, COSV51108238; called by muse, mutect2, varscan2
- KIF2B | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.107); catalogued as rs371085430, COSV52127441; called by mutect2, varscan2
- KIF7 | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1374666466; called by muse, mutect2, varscan2
- LPAR1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370198772; called by muse, mutect2, varscan2
- MUC20 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 46/736 reads (6%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs868368511; called by muse, mutect2
- MYH4 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs201207535, COSV55118855; called by muse, mutect2, varscan2
- PALB2 | c.1537A>G p.T513A | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1060502741; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCNX2 | c.3840C>T p.L1280= | Splice Region (SNP) | VAF 28/140 reads (20%) | catalogued as rs746899040, COSV50785748; called by muse, mutect2, varscan2
- PIWIL1 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99806613; called by muse, mutect2, varscan2
- PRKDC | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs769242222; called by mutect2, varscan2
- SMARCA2 | c.3782G>A p.R1261Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV61812604; called by muse, mutect2
- SORCS3 | c.2380C>T p.R794W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366580746, COSV63793656, COSV63795971; called by muse, mutect2, varscan2
- TENM1 | c.7408G>A p.D2470N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1413293277; called by muse, mutect2, varscan2
- TTN | c.18239C>T p.T6080M (on ENST00000591111; = p.T5153M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/167 reads (23%) | PolyPhen probably damaging (0.988); catalogued as rs199564845; ClinVar: uncertain significance; called by muse, varscan2
- UNC5CL | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.023); catalogued as COSV99770631; called by muse, mutect2, varscan2
- WNK3 | c.3812G>A p.R1271H | Missense Mutation (SNP) | VAF 27/171 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs868955784, COSV63616569; called by muse, mutect2, varscan2
- ZBED9 | c.1750G>T p.V584F | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV71729330; called by muse, mutect2, varscan2
- ANKRD30B | c.1688C>G p.S563* | Nonsense Mutation (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- ANO3 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC152 | c.148T>C p.C50R | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.238); called by muse, mutect2
- CCPG1 | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CTNNB1 | c.16del p.D6Ifs*2 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- DMXL1 | c.2164G>C p.V722L | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- DOCK1 | c.1390-2A>G p.X464_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- EPB41L3 | c.2468T>A p.V823D | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2
- EPHA2 | c.1591G>T p.G531* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- HLA-B | c.696_697del p.F232Lfs*21 | Frame Shift Del (DEL) | VAF 9/93 reads (10%) | called by mutect2, pindel*
- HMCN1 | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NAV2 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBP2 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- PCDHB14 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PMP22 | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RGPD8 | c.140A>T p.K47I | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TAOK2 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- TEK | c.529C>T p.H177Y | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTK | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTLL13P | c.2195C>T p.T732I | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- TTLL5 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); called by muse, mutect2
- WWC3 | c.1243C>T p.L415F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); called by mutect2, varscan2
- BCORL1 | c.2574G>A p.A858= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs199970788; called by muse, mutect2, varscan2
- DNAH11 | c.9666G>A p.V3222= | Silent (SNP) | VAF 35/164 reads (21%) | called by muse, mutect2, varscan2
- ELOA | c.1596C>T p.S532= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as rs769137200; called by muse, mutect2, varscan2
- EWSR1 | c.42G>A p.A14= | Silent (SNP) | VAF 23/107 reads (21%) | catalogued as rs775729620; called by muse, mutect2
- GEMIN4 | c.1068C>T p.S356= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7335G>A p.L2445= | Silent (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2, varscan2
- KRTAP5-3 | c.570C>T p.C190= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs12808755, COSV68791240; called by muse, varscan2
- MAP3K15 | c.660G>T p.L220= | Silent (SNP) | VAF 46/164 reads (28%) | called by muse, mutect2, varscan2
- MTHFD1L | c.973C>T p.L325= | Silent (SNP) | VAF 31/145 reads (21%) | called by muse, mutect2, varscan2
- RBL2 | c.378C>T p.I126= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as rs112708377; called by muse, mutect2, varscan2
- SI | c.3120G>A p.K1040= | Silent (SNP) | VAF 58/265 reads (22%) | catalogued as rs908730367; called by muse, mutect2, varscan2
- SORCS1 | c.819C>T p.Y273= | Silent (SNP) | VAF 57/266 reads (21%) | catalogued as rs1163511783; called by muse, mutect2, varscan2
- THSD7A | c.4341G>A p.P1447= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as rs762226111, COSV70267009; called by muse, mutect2, varscan2
- TNFRSF8 | c.1719C>T p.S573= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs776112690, COSV99821255; called by muse, varscan2
- ADAMTS13 | c.825-229C>A | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- CCDC144NL | n.1068C>G | RNA (SNP) | VAF 30/126 reads (24%) | called by muse, mutect2, varscan2
- GNL3L | c.*3G>A | 3'UTR (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- MIR4477B | chr9:63817981 C>T | 5'Flank (SNP) | VAF 5/52 reads (10%) | catalogued as rs1430629446; called by muse, varscan2
- PWWP3A | chr19:1373168 G>A | 3'Flank (SNP) | VAF 13/63 reads (21%) | catalogued as rs374404267; called by muse, mutect2
